TCGA case TCGA-AA-A02R — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/764c97c9-01d3-45cb-86bd-f8a52b5468da

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 84 years; Vital status: Dead; Days to death: 670 days (1.8 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.0; Tissue or organ of origin: Cecum; Site of resection or biopsy: Cecum; Classification of tumor: primary; Age at diagnosis: 84.4 years (30,834 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 18; Lymphatic invasion present: Yes; Vascular invasion present: Yes.

Follow-up (1 entry)
- Days to follow up: 670 days (1.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 2.67 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-A02R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,000 mg.
  Slide TCGA-AA-A02R-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 9; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
  Slide TCGA-AA-A02R-01A-02-BS2: Section location: Bottom; Percent tumor cells: 69; Percent tumor nuclei: 80; Percent normal cells: 25; Percent necrosis: 1; Percent stromal cells: 5; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
  Slide TCGA-AA-A02R-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
- Sample TCGA-AA-A02R-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-A02R-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 2.67; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 670 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 670 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 670 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-A02R-01A-01D-A008-01): tumor purity 0.66, ploidy 2.05, whole-genome doublings 0.
